ORGANOID case 68 — Pancreas Cancer Organoid Profiling (ORGANOID-PANCREATIC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/d7ac181d-ce1b-4672-953e-aeff29615636

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino.

Biospecimens (2 samples)
- Samples S108, S192 (2 with the same recorded description): Sample type: Next Generation Cancer Model; Tissue type: Normal; Specimen type: 3D Organoid.
